Gene-level copy-number profile of tumor specimen TCGA-04-1655-01A from TCGA case TCGA-04-1655, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 49.2 years (17,988 days).
Specimen TCGA-04-1655-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.496e4773-961e-4a65-8f28-8997bde6290c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1655-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3aad146-5bde-449f-ab50-1434e18da028

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 922; copy number 2: 6,208; copy number 3: 14,132; copy number 4: 14,865; copy number 5: 9,537; copy number 6: 6,116; copy number 7: 6,081; copy number 8: 1,236; copy number 9: 545; copy number 10: 67; copy number 11: 46; copy number 22: 36; copy number 26: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1655-01A-01D-0559-01): tumor purity 0.94, ploidy 4.67, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 717 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:114,854,863–117,778,506, 67 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr3:177,816,865–198,222,513, 463 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr6:98,780,257–107,986,031, 100 genes, copy number 9–26 (broad region; genes not listed).
- chr20:18,059,493–21,755,350, 87 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
